Somatic mutation profile of tumor specimen TCGA-22-5477-01A (aliquot TCGA-22-5477-01A-01D-1632-08) from TCGA case TCGA-22-5477, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 65.9 years (24,055 days).
Specimen TCGA-22-5477-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f2e1a51-547e-4dda-b20d-7d65689a532e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5477-11A (Solid Tissue Normal), aliquot TCGA-22-5477-11A-11D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c94952a-c531-4566-a4da-080eb262a7c7

The open-access MAF lists 179 somatic variants for this specimen: 121 protein-altering or splice-affecting, 55 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 55, Nonsense Mutation 7, 5'Flank 1, Intron 1, Frame Shift Ins 1, Splice Site 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 22/24 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FANCA | c.3482C>T p.T1161M | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs142833057; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 28/34 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- PDYN | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 72/128 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606939, CM107861, COSV54100812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 24/31 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.3304G>T p.D1102Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.285); catalogued as COSV52218398; called by muse, mutect2
- ABCB10 | c.1363C>A p.L455M | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); catalogued as COSV60619837; called by muse, mutect2
- ACSM3 | c.1670G>A p.R557K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55499883; called by muse, mutect2, varscan2
- ADGRB1 | c.3898C>T p.P1300S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1348242038, COSV60091972; called by muse, mutect2, varscan2
- AKAP12 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); catalogued as rs757336172, COSV53570366; called by muse, mutect2, varscan2
- ALX1 | c.769C>G p.R257G | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs921513196, COSV57491205; called by muse, mutect2, varscan2
- AMDHD2 | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV53549664; called by muse, mutect2
- BCLAF1 | c.2338C>T p.H780Y | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.301); catalogued as COSV50356826; called by muse, mutect2, varscan2
- C12orf65 | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as rs750994936, COSV53515761; called by muse, mutect2, varscan2
- CACNA1E | c.2758C>A p.R920S | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV100702048, COSV62382687; called by muse, mutect2, varscan2
- CACNA1G | c.3063C>T p.A1021= | Splice Region (SNP) | VAF 12/27 reads (44%) | catalogued as rs771431361, COSV61720351; called by muse, mutect2, varscan2
- CDK12 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101420303, COSV70999322; called by muse, varscan2
- CHD7 | c.1063T>C p.S355P | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV71107270; called by muse, mutect2, varscan2
- CHID1 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV60257869; called by muse, varscan2
- CHST8 | c.1119C>G p.F373L | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV52856327, COSV52862175; called by muse, mutect2, varscan2
- CIRBP | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV58010448; called by muse, mutect2, varscan2
- CNGA2 | c.1007C>T p.T336I | Missense Mutation (SNP) | VAF 109/118 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61703254; called by muse, mutect2, varscan2
- CNKSR2 | c.3043G>A p.E1015K | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as COSV65278717; called by muse, mutect2, varscan2
- COG2 | c.906A>T p.K302N | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV64186001; called by muse, mutect2, varscan2
- COG5 | c.59C>A p.A20E | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.077); catalogued as COSV51742966; called by muse, mutect2, varscan2
- CPED1 | c.2778dup p.H927Tfs*4 | Frame Shift Ins (INS) | VAF 34/101 reads (34%) | catalogued as rs777945397; called by mutect2, varscan2
- DAP | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV50143155; called by muse, mutect2, varscan2
- DSCAM | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 65/78 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV68021086; called by muse, mutect2, varscan2
- DSG1 | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57133282; called by muse, mutect2, varscan2
- DST | c.20719C>G p.L6907V (on ENST00000361203 / NM_001374722.1; = p.L4604V on NM_015548.5) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV54998274, COSV55014751; called by muse, mutect2, varscan2
- EHMT1 | c.578C>A p.A193D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV58370787; called by muse, mutect2, varscan2
- ENTPD2 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs1487778724, COSV57074610; called by muse, mutect2, varscan2
- EPHA7 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV65168605; called by muse, mutect2, varscan2
- ETV6 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 61/109 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.165); catalogued as COSV67148224; called by muse, mutect2, varscan2
- FAT4 | c.7070T>A p.V2357D | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.579); catalogued as COSV58672025; called by muse, mutect2, varscan2
- FRMD8 | c.854A>G p.H285R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV58211783; called by muse, mutect2, varscan2
- FSIP2 | c.20249C>G p.A6750G | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV58078464; called by muse, mutect2, varscan2
- GABRG1 | c.1147C>A p.H383N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.139); catalogued as COSV54950107; called by muse, mutect2, varscan2
- GALNT2 | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 78/187 reads (42%) | catalogued as COSV64192904, COSV64194660; called by muse, mutect2, varscan2
- GC | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV56735363; called by muse, mutect2, varscan2
- GCC2 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV59174067; called by muse, mutect2, varscan2
- GSE1 | c.3002C>T p.P1001L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as COSV53669459; called by muse, mutect2
- HDGFL2 | c.1636C>T p.L546F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.654); catalogued as COSV56681335; called by muse, mutect2, varscan2
- HDX | c.1198C>G p.H400D | Missense Mutation (SNP) | VAF 35/38 reads (92%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV52973097, COSV52981752; called by muse, mutect2, varscan2
- KAT6A | c.1108C>T p.L370F | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV55902786, COSV55910733; called by muse, mutect2, varscan2
- KDR | c.1282C>G p.L428V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV55758251; called by muse, mutect2, varscan2
- KMT2D | c.7177G>T p.E2393* | Nonsense Mutation (SNP) | VAF 19/25 reads (76%) | catalogued as COSV56411892, COSV56430672; called by muse, mutect2, varscan2
- LAMA2 | c.5291A>G p.E1764G | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs141950826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LDLR | c.2333G>A p.R778K | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV52941674; called by muse, mutect2, varscan2
- LRBA | c.4523A>G p.Q1508R | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV63950067; called by muse, mutect2, varscan2
- LRP1 | c.11694G>C p.E3898D | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.057); catalogued as COSV54502353, COSV54515211; called by muse, mutect2, varscan2
- MYH4 | c.2564A>T p.N855I | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV55112434; called by muse, mutect2
- MYT1L | c.1259C>G p.S420C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67708655; called by muse, mutect2, varscan2
- NLRC4 | c.993G>C p.L331F | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV61591442; called by muse, mutect2, varscan2
- NOL9 | c.1480C>T p.H494Y | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as COSV66625313; called by muse, mutect2, varscan2
- NOMO2 | c.1165G>T p.V389F | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV57915578; called by muse, mutect2, varscan2
- NUDT19 | c.882C>G p.I294M | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV67959313; called by muse, mutect2, varscan2
- OPRD1 | c.877G>C p.D293H | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV52380165; called by muse, mutect2, varscan2
- OR13C9 | c.687C>G p.H229Q | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV52240676; called by muse, mutect2, varscan2
- OR4S2 | c.18C>A p.N6K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV56745922, COSV56748516; called by muse, mutect2, varscan2
- OTUD7A | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV61036055; called by muse, mutect2, varscan2
- PCARE | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.148); catalogued as COSV59053116; called by muse, mutect2, varscan2
- PCCB | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV52443542; called by muse, mutect2, varscan2
- PCDH11X | c.1334C>A p.P445H | Missense Mutation (SNP) | VAF 97/109 reads (89%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV53443783; called by muse, mutect2, varscan2
- PCDHB11 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.072); catalogued as rs782453183, COSV61309882; called by muse, mutect2, varscan2
- PLA2G5 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs387906796, CM1110072, COSV100908282, COSV64282789; ClinVar: affects; called by muse, mutect2, varscan2
- PLAAT5 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV57136161, COSV57136172; called by muse, mutect2, varscan2
- PLEC | c.1178C>T p.S393L (on ENST00000322810 / NM_201380.4; = p.S283L on NM_000445.5) | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782798891, COSV59604630; called by muse, mutect2, varscan2
- PMPCA | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs771359205, COSV65508938; called by muse, mutect2, varscan2
- PNPLA7 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV52994353; called by muse, mutect2, varscan2
- PRDX1 | c.185G>C p.R62T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV53113069; called by muse, mutect2, varscan2
- PRICKLE1 | c.1267G>C p.G423R | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61541868; called by muse, mutect2, varscan2
- PRKDC | c.10295C>G p.S3432* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV58043224; called by muse, mutect2, varscan2
- PRPF8 | c.1375C>G p.L459V | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV59260637; called by muse, mutect2, varscan2
- PUM2 | c.476G>C p.R159T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.339); catalogued as COSV57577907, COSV57584324; called by muse, mutect2, varscan2
- PXDNL | c.4234G>A p.E1412K | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV62478439; called by muse, mutect2
- RABEPK | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV52334111; called by muse, mutect2, varscan2
- RICTOR | c.3895A>G p.R1299G | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV57117183; called by muse, mutect2
- RNF141 | c.255T>G p.I85M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV56416373; called by muse, mutect2
- RNF40 | c.1002G>A p.M334I | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV61213684; called by muse, mutect2, varscan2
- RP1 | c.1843T>A p.F615I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as COSV55110293; called by muse, mutect2
- RPS21 | c.232A>T p.I78F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.221); catalogued as COSV54155733; called by muse, mutect2, varscan2
- RSRC1 | c.14C>A p.S5* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as COSV55823551; called by muse, mutect2, varscan2
- RTTN | c.6179C>G p.S2060C | Missense Mutation (SNP) | VAF 51/63 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV55341476; called by muse, mutect2, varscan2
- SHANK3 | c.4346C>G p.S1449C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV53183583; called by muse, mutect2, varscan2
- SIGLEC6 | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV58431959, COSV58434881; called by muse, mutect2, varscan2
- SLC6A12 | c.1480T>C p.W494R | Missense Mutation (SNP) | VAF 103/160 reads (64%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.757); catalogued as rs1293639337, COSV62883905; called by muse, mutect2, varscan2
- SLIT1 | c.697C>G p.R233G | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV56582555, COSV99820535; called by muse, mutect2, varscan2
- SLTM | c.223C>G p.P75A | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs753684222, COSV51053281; called by muse, mutect2, varscan2
- SORCS1 | c.1456G>T p.D486Y | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53842285; called by muse, mutect2, varscan2
- SQSTM1 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV62434202; called by muse, mutect2, varscan2
- SRP72 | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61376877; called by muse, mutect2
- SSMEM1 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV52832997; called by muse, mutect2, varscan2
- STAB2 | c.7486G>A p.E2496K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV66334338, COSV66336904; called by muse, mutect2, varscan2
- TAS2R16 | c.451C>G p.Q151E | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.08); catalogued as rs765921681, COSV50796821; called by muse, mutect2, varscan2
- TAS2R41 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV68764923; called by muse, mutect2, varscan2
- TDRD3 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as COSV52153221; called by muse, mutect2
- TFIP11 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs151208617, COSV68020308; called by muse, mutect2, varscan2
- TGFBR3 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV53021833, COSV53027388; called by muse, mutect2, varscan2
- TMEM268 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55985576; called by muse, mutect2, varscan2
- TNC | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs141417605; called by muse, mutect2, varscan2
- TRIM24 | c.2683G>A p.E895K (on ENST00000343526 / NM_015905.3; = p.E861K on NM_003852.4) | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV58969129; called by muse, mutect2, varscan2
- TRIM45 | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV56712511; called by muse, mutect2, varscan2
- TTC30B | c.375C>A p.S125R | Missense Mutation (SNP) | VAF 110/140 reads (79%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV68809215; called by muse, mutect2, varscan2
- TTN | c.100823C>G p.S33608C (on ENST00000591111; = p.S26184C on NM_003319.4) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | PolyPhen possibly damaging (0.808); catalogued as COSV100603251, COSV59893612; called by muse, mutect2
- UBE3B | c.1901G>A p.R634K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55091331; called by muse, mutect2, varscan2
- UPF1 | c.1207G>A p.A403T (on ENST00000599848 / NM_001297549.2; = p.A392T on NM_002911.4) | Missense Mutation (SNP) | VAF 116/280 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as COSV53193686; called by muse, mutect2, varscan2
- VEGFC | c.302C>G p.S101* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV54593905; called by muse, mutect2, varscan2
- VPS13C | c.2899C>T p.H967Y (on ENST00000644861 / NM_020821.3; = p.H924Y on NM_017684.5) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51122196; called by muse, mutect2, varscan2
- YBX1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV58437237; called by muse, mutect2, varscan2
- ZAN | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs747613197, COSV61805163; called by muse, mutect2, varscan2
- ZFHX4 | c.3353G>C p.C1118S | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.015); catalogued as COSV50500896; called by muse, mutect2, varscan2
- ZNF322 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as COSV101338495; called by mutect2, varscan2
- ZNF37A | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV61072536; called by muse, mutect2, varscan2
- ZNF57 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV60982596; called by muse, mutect2, varscan2
- ZNF606 | c.2341C>T p.Q781* | Nonsense Mutation (SNP) | VAF 56/128 reads (44%) | catalogued as COSV100071634, COSV58705135; called by muse, mutect2, varscan2
- ZNF613 | c.1831G>A p.D611N (on ENST00000293471 / NM_001031721.4; = p.D575N on NM_024840.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV53270861; called by muse, mutect2, varscan2
- ZNF648 | c.933C>G p.F311L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV60569760; called by muse, mutect2, varscan2
- CKAP2L | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 95/213 reads (45%) | called by muse, mutect2, varscan2
- TRAFD1 | c.1279+1_1279+16del p.X427_splice | Splice Site (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- TUBB2B | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- A2ML1 | c.1161C>T p.F387= | Silent (SNP) | VAF 104/172 reads (60%) | catalogued as COSV55285865; called by muse, mutect2, varscan2
- ADARB2 | c.543G>T p.A181= | Silent (SNP) | VAF 13/15 reads (87%) | catalogued as COSV67215035; called by muse, mutect2, varscan2
- AHNAK | c.7053C>A p.P2351= | Silent (SNP) | VAF 46/160 reads (29%) | catalogued as COSV57203911; called by muse, mutect2, varscan2
- ANKRD11 | c.4020C>G p.L1340= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV56355112; called by muse, mutect2, varscan2
- ATMIN | c.2358G>A p.Q786= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV55145159; called by muse, mutect2, varscan2
- ATP9A | c.270C>T p.C90= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV58763235; called by muse, mutect2, varscan2
- ATP9B | c.843G>C p.V281= | Silent (SNP) | VAF 47/57 reads (82%) | catalogued as COSV56946179; called by muse, mutect2, varscan2
- BBS2 | c.207C>G p.L69= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV55325144; called by muse, mutect2, varscan2
- CABLES2 | c.612G>A p.L204= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV54155741; called by muse, mutect2
- CACNG5 | c.420C>A p.L140= | Silent (SNP) | VAF 48/144 reads (33%) | catalogued as COSV50054759; called by muse, mutect2, varscan2
- CAD | c.3297T>C p.N1099= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as rs1173856019, COSV53023689; called by muse, mutect2, varscan2
- CDK13 | c.4071C>T p.S1357= | Silent (SNP) | VAF 49/140 reads (35%) | catalogued as COSV51696441; called by muse, mutect2, varscan2
- COL12A1 | c.1671C>T p.F557= | Silent (SNP) | VAF 76/186 reads (41%) | catalogued as COSV59389717; called by muse, mutect2, varscan2
- COL7A1 | c.2067G>A p.V689= | Silent (SNP) | VAF 28/34 reads (82%) | catalogued as COSV60391275; called by muse, mutect2, varscan2
- DPP4 | c.1869A>G p.R623= | Silent (SNP) | VAF 40/46 reads (87%) | catalogued as COSV62105099; called by muse, mutect2, varscan2
- EFCAB6 | c.2196G>A p.L732= | Silent (SNP) | VAF 54/186 reads (29%) | catalogued as COSV53058318; called by muse, mutect2, varscan2
- EME1 | c.1167G>A p.K389= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV56813702; called by muse, mutect2, varscan2
- EXTL2 | c.936C>T p.S312= | Silent (SNP) | VAF 35/49 reads (71%) | catalogued as COSV64472681; called by muse, mutect2, varscan2
- FAM234A | c.930G>A p.E310= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV56991511; called by muse, mutect2, varscan2
- FMN2 | c.474G>A p.P158= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1198977248, COSV60417397; called by muse, mutect2, varscan2
- GK2 | c.1134G>C p.G378= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV62626146, COSV62626660; called by muse, mutect2, varscan2
- GRK3 | c.858C>T p.H286= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs759640133, COSV60793432; called by muse, mutect2, varscan2
- JOSD2 | c.129C>T p.A43= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as rs1176235475, COSV65349231; called by muse, mutect2, varscan2
- KBTBD6 | c.2024G>A p.*675= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV65270895; called by muse, mutect2, varscan2
- KIF2C | c.2100C>T p.V700= | Silent (SNP) | VAF 40/48 reads (83%) | catalogued as rs1290702333, COSV64763824, COSV64763898; called by muse, varscan2
- KLRC3 | c.561A>T p.T187= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as COSV67249862; called by muse, mutect2, varscan2
- KTN1 | c.1185T>C p.H395= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs777809250, COSV68022348; called by muse, mutect2, varscan2
- LRRK2 | c.5868T>C p.D1956= | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as COSV54144329; called by muse, mutect2, varscan2
- MUC16 | c.20205C>T p.I6735= | Silent (SNP) | VAF 76/170 reads (45%) | catalogued as COSV67445615, COSV67494852; called by muse, mutect2, varscan2
- MYOM1 | c.3126G>A p.P1042= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs774428810, COSV55285765; called by muse, mutect2, varscan2
- NACA2 | c.213G>C p.R71= | Silent (SNP) | VAF 87/226 reads (38%) | catalogued as COSV101478560, COSV71713085; called by muse, mutect2, varscan2
- NOMO2 | c.1164G>T p.T388= | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as COSV57915596; called by muse, mutect2, varscan2
- NPR1 | c.1689C>T p.L563= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs565874749, COSV64117285; called by muse, mutect2, varscan2
- NUAK1 | c.1521G>T p.P507= | Silent (SNP) | VAF 35/55 reads (64%) | catalogued as COSV54600560; called by muse, mutect2, varscan2
- OR10H3 | c.138C>T p.I46= | Silent (SNP) | VAF 109/272 reads (40%) | catalogued as COSV59943463; called by muse, mutect2, varscan2
- OR2M2 | c.444C>T p.S148= | Silent (SNP) | VAF 12/262 reads (5%) | catalogued as COSV62897802; called by muse, mutect2
- OR5F1 | c.612T>A p.G204= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV53545265; called by muse, mutect2, varscan2
- OR6N1 | c.753C>T p.F251= | Silent (SNP) | VAF 63/110 reads (57%) | catalogued as COSV58647411; called by muse, mutect2, varscan2
- PCDH8 | c.60C>A p.L20= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV58810849; called by muse, mutect2, varscan2
- PCK1 | c.1332C>A p.V444= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV60126188; called by muse, mutect2, varscan2
- PSMA8 | c.666T>C p.N222= | Silent (SNP) | VAF 68/81 reads (84%) | catalogued as COSV57601069; called by muse, mutect2, varscan2
- PTK2 | c.2175C>T p.S725= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV61782585; called by muse, mutect2, varscan2
- RAC2 | c.201C>G p.L67= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV50773824, COSV50773862; called by muse, mutect2, varscan2
- SGCB | c.789C>G p.V263= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV67340548; called by muse, mutect2, varscan2
- SLC3A2 | c.36C>T p.V12= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs148497008; called by muse, mutect2, varscan2
- SLC6A13 | c.810C>G p.L270= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV58255361, COSV58261105; called by muse, mutect2
- SLFN12 | c.792C>T p.I264= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as rs544335792, COSV59225232; called by muse, mutect2, varscan2
- SPON1 | c.606C>T p.C202= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs782016066, COSV59964332; called by muse, mutect2
- TBL1XR1 | c.258C>T p.A86= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as rs754803040, COSV61789352; called by muse, mutect2, varscan2
- TMEM132B | c.1485G>C p.T495= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV54745063; called by muse, mutect2, varscan2
- TTN | c.11838G>A p.L3946= (on ENST00000591111; = p.L3900= on NM_003319.4) | Silent (SNP) | VAF 21/28 reads (75%) | catalogued as COSV59893644, COSV59962503; called by muse, mutect2, varscan2
- UBL7 | c.123A>T p.S41= | Silent (SNP) | VAF 47/141 reads (33%) | catalogued as COSV63705688; called by muse, mutect2, varscan2
- VPS53 | c.1035T>G p.L345= (on ENST00000571805 / NM_001366253.2; = p.L316= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV52126270; called by muse, mutect2
- WARS2 | c.474C>T p.L158= | Silent (SNP) | VAF 39/61 reads (64%) | catalogued as COSV52475781, COSV52481750; called by muse, mutect2, varscan2
- ZNF462 | c.2070G>A p.V690= | Silent (SNP) | VAF 65/165 reads (39%) | catalogued as rs147884090; called by muse, mutect2, varscan2
- MYADM | chr19:53874161 C>T | 3'Flank (SNP) | VAF 28/127 reads (22%) | catalogued as COSV61238604; called by muse, mutect2, varscan2
- RUSC1 | chr1:155320877 G>A | 5'Flank (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2
- TNIK | c.2406+465C>G | Intron (SNP) | VAF 57/110 reads (52%) | catalogued as COSV52674032; called by muse, mutect2, varscan2
